Somatic mutation profile of tumor specimen C3L-00104-01 (aliquot CPT0092440009) from CPTAC case C3L-00104, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.0 years (21,197 days).
Specimen C3L-00104-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d4258ff-8362-45b6-a754-a4c9fd1f8cfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00104-31 (Blood Derived Normal), aliquot CPT0093800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f34b16a2-1124-4ccc-93a4-7352fe9b5cc3

The open-access MAF lists 89 somatic variants for this specimen: 59 protein-altering or splice-affecting, 19 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Intron 6, Nonsense Mutation 3, RNA 3, 3'UTR 1, In Frame Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 371/703 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 172/236 reads (73%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV64289114, COSV64289498, COSV64301765; called by muse, mutect2, varscan2
- RB1 | c.1960+2T>C p.X654_splice | Splice Site (SNP) | VAF 71/102 reads (70%) | hotspot (GDC flag); catalogued as rs587776780, CS145470, COSV57295816, COSV57324879; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 327/454 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AKAP6 | c.5564G>A p.R1855H | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1050582204, COSV55218444; called by muse, mutect2, varscan2
- APBA1 | c.2389G>A p.V797M | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777421578, COSV99596570; called by muse, mutect2, varscan2
- C1QTNF2 | c.445C>T p.R149W (on ENST00000393975; = p.R104W on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs766351381, COSV67432948; called by muse, mutect2
- CACNA1A | c.2435C>T p.T812M | Missense Mutation (SNP) | VAF 371/928 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs748099275, COSV64208189; called by muse, mutect2, varscan2
- CARNS1 | c.2405G>A p.R802H | Missense Mutation (SNP) | VAF 152/332 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs776062703, COSV57047398; called by muse, mutect2, varscan2
- CDH18 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs759064016, COSV56914916, COSV56935577; called by muse, mutect2, varscan2
- CFAP45 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 219/454 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs200252683, COSV63647949; called by muse, mutect2, varscan2
- CFHR3 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 205/559 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as rs372197677; called by muse, mutect2, varscan2
- CYP4B1 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs200083913, COSV54723008; called by muse, mutect2, varscan2
- DNAH6 | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1444735326; called by muse, mutect2, varscan2
- EP400 | c.6565C>T p.R2189* | Nonsense Mutation (SNP) | VAF 47/117 reads (40%) | catalogued as rs1171496476; called by muse, mutect2, varscan2
- EPN1 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1231242314, COSV50036012; called by muse, mutect2, varscan2
- ESM1 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV101195716, COSV67318511; called by muse, mutect2, varscan2
- FBXL19 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs771051806, COSV57941046; called by muse, mutect2, varscan2
- HFM1 | c.1591C>T p.L531F | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557483909; called by muse, mutect2, varscan2
- L3MBTL2 | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 148/317 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs780186631; called by muse, mutect2, varscan2
- MAGEC2 | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 52/55 reads (95%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV55997689; called by muse, mutect2, varscan2
- MOCOS | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 260/626 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs141550556; called by muse, mutect2, varscan2
- MUC5B | c.6809C>T p.T2270M | Missense Mutation (SNP) | VAF 370/1266 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs759541226; called by muse, varscan2
- MXRA5 | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs140956390, COSV54223188; called by muse, mutect2, varscan2
- NKAIN2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.939); catalogued as rs550760834, COSV63661210; called by muse, mutect2, varscan2
- NLRP5 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as rs577761633, COSV66761737; called by muse, mutect2
- NPTX2 | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 80/153 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402756746, COSV99675071; called by muse, mutect2, varscan2
- NXF3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1271800605; called by muse, mutect2, varscan2
- PIF1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 197/258 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as rs201996206, COSV51423628; called by muse, mutect2, varscan2
- PLCG2 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.508); catalogued as rs780141402; called by muse, mutect2, varscan2
- PPARGC1A | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs754602547, COSV104393823; called by muse, mutect2, varscan2
- PZP | c.1540G>C p.G514R | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs746115447; called by muse, mutect2, varscan2
- REV3L | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as rs778759473; called by muse, mutect2, varscan2
- RGPD3 | c.2303C>G p.S768C | Missense Mutation (SNP) | VAF 167/1094 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs775744400, COSV58739760; called by muse, mutect2, varscan2
- TFRC | c.2092C>T p.R698* | Nonsense Mutation (SNP) | VAF 161/365 reads (44%) | catalogued as rs373764388, COSV100786629; called by muse, mutect2, varscan2
- TRPC1 | c.1535G>A p.R512H (on ENST00000476941 / NM_001251845.2; = p.R478H on NM_003304.4) | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745396101, COSV56422583; called by muse, mutect2, varscan2
- WNK4 | c.3496C>T p.R1166W | Missense Mutation (SNP) | VAF 177/411 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770685193, COSV55903374; called by muse, mutect2, varscan2
- ZNF536 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 175/436 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100835381, COSV62827327; called by muse, mutect2, varscan2
- ZNF574 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as rs1174322133; called by muse, mutect2, varscan2
- ADAMTS19 | c.1847A>G p.D616G | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- C2orf16 | c.3560C>G p.P1187R | Missense Mutation (SNP) | VAF 88/397 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CD81 | c.697A>T p.S233C | Missense Mutation (SNP) | VAF 32/578 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- COL5A3 | c.3844C>A p.P1282T | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ETFA | c.998A>C p.K333T | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- FANCA | c.3932G>C p.S1311T | Missense Mutation (SNP) | VAF 77/96 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INPP5D | c.2140T>A p.S714T (on ENST00000445964 / NM_001017915.3; = p.S713T on NM_005541.5) | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- INTS3 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 54/340 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- LRRIQ4 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- NLRP6 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRIP1 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6B1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RAB24 | c.231_233del p.Y78del | In Frame Del (DEL) | VAF 57/190 reads (30%) | called by pindel, varscan2
- RFX7 | c.3514G>T p.G1172* (on ENST00000559447 / NM_001368074.1; = p.G1269* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 91/130 reads (70%) | called by muse, mutect2, varscan2
- STAT4 | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM6 | c.3674T>G p.L1225R | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WDR74 | c.798G>C p.K266N | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZC3H11A | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 2678/3662 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZFYVE16 | c.2269C>G p.Q757E | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF711 | c.770T>A p.V257D | Missense Mutation (SNP) | VAF 73/88 reads (83%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- AP1G2 | c.762T>A p.L254= | Silent (SNP) | VAF 134/317 reads (42%) | called by muse, mutect2, varscan2
- C14orf28 | c.219T>C p.N73= | Silent (SNP) | VAF 66/137 reads (48%) | called by muse, mutect2, varscan2
- C6orf132 | c.2769C>T p.D923= | Silent (SNP) | VAF 72/173 reads (42%) | called by muse, mutect2, varscan2
- CHPF | c.450C>T p.F150= | Silent (SNP) | VAF 105/220 reads (48%) | called by muse, mutect2, varscan2
- FEZF1 | c.375G>T p.L125= | Silent (SNP) | VAF 84/175 reads (48%) | called by muse, mutect2, varscan2
- GABRA1 | c.372G>A p.P124= | Silent (SNP) | VAF 168/466 reads (36%) | catalogued as rs1378731581; ClinVar: likely benign; called by muse, mutect2, varscan2
- KPNA2 | c.1029G>T p.L343= | Silent (SNP) | VAF 85/451 reads (19%) | called by muse, mutect2, varscan2
- MAIP1 | c.618A>G p.T206= | Silent (SNP) | VAF 86/178 reads (48%) | called by muse, varscan2
- MROH5 | c.1149C>T p.Y383= | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as rs749142209, COSV101435968, COSV71301757; called by muse, mutect2, varscan2
- NCKAP1L | c.2445C>T p.F815= | Silent (SNP) | VAF 108/312 reads (35%) | catalogued as rs142923538; called by muse, mutect2, varscan2
- OR2A1 | c.246G>A p.A82= | Silent (SNP) | VAF 184/714 reads (26%) | catalogued as rs755391311, COSV68822778; called by muse, mutect2, varscan2
- OR51B5 | c.78C>T p.S26= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as rs138029050; called by muse, mutect2, varscan2
- OR52J3 | c.402C>T p.Y134= | Silent (SNP) | VAF 138/342 reads (40%) | catalogued as rs149427006, COSV66747934; called by muse, mutect2
- SLC5A12 | c.159C>T p.V53= | Silent (SNP) | VAF 26/498 reads (5%) | catalogued as rs373883178; called by muse, mutect2
- SLC9C2 | c.1269C>T p.Y423= | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as rs138213092; called by muse, mutect2, varscan2
- THSD7B | c.174C>T p.P58= | Silent (SNP) | VAF 62/154 reads (40%) | catalogued as rs772035764; called by muse, mutect2
- TRAV10 | c.240C>T p.N80= | Silent (SNP) | VAF 120/314 reads (38%) | catalogued as rs189035449; called by muse, mutect2, varscan2
- TRH | c.400C>A p.R134= | Silent (SNP) | VAF 219/520 reads (42%) | called by muse, mutect2, varscan2
- ZNF536 | c.81C>T p.N27= | Silent (SNP) | VAF 58/137 reads (42%) | catalogued as rs1346301084, COSV62824162; called by muse, mutect2, varscan2
- ACAA2 | chr18:49814096 G>A | 5'Flank (SNP) | VAF 140/380 reads (37%) | called by muse, varscan2
- FRMD8P1 | n.693G>A | RNA (SNP) | VAF 128/143 reads (90%) | catalogued as rs1340674966; called by muse, mutect2, varscan2
- IGFN1 | c.1241+3365G>A | Intron (SNP) | VAF 102/264 reads (39%) | called by muse, mutect2, varscan2
- KMT2B | c.6960-39G>A | Intron (SNP) | VAF 135/188 reads (72%) | catalogued as rs756947943, COSV55863233; called by muse, mutect2, varscan2
- POU4F3 | c.*33A>G | 3'UTR (SNP) | VAF 162/446 reads (36%) | called by muse, mutect2, varscan2
- SPAG6 | c.121+86G>T | Intron (SNP) | VAF 24/265 reads (9%) | called by muse, mutect2
- SSTR5-AS1 | n.611C>T | RNA (SNP) | VAF 44/117 reads (38%) | catalogued as rs1283370015; called by muse, mutect2, varscan2
- SYT7 | c.215+5176C>T | Intron (SNP) | VAF 81/214 reads (38%) | catalogued as rs962295988; called by muse, mutect2, varscan2
- SYTL2 | c.1459+3142C>T | Intron (SNP) | VAF 77/190 reads (41%) | called by muse, mutect2, varscan2
- TTN | c.34265-3943G>A | Intron (SNP) | VAF 20/48 reads (42%) | called by mutect2, varscan2
- ZNF849P | n.539T>A | RNA (SNP) | VAF 156/362 reads (43%) | called by muse, mutect2, varscan2
